Somatic mutation profile of tumor specimen C3L-07982-01 (aliquot CPT0481180006) from CPTAC case C3L-07982, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 69.1 years (25,222 days).
Specimen C3L-07982-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cb47568-9ded-4e88-8331-b3fdb4b8db63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07982-31 (Blood Derived Normal), aliquot CPT0481330003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2981ef5b-5742-4d27-b2c1-ec51cf661858

The open-access MAF lists 231 somatic variants for this specimen: 174 protein-altering or splice-affecting, 48 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 48, Nonsense Mutation 7, Intron 4, Splice Region 2, Frame Shift Del 2, 5'UTR 2, Splice Site 2, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOL4 | c.1267T>A p.L423M | Missense Mutation (SNP) | VAF 39/193 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52337695, COSV52338459, COSV52349574; called by muse, mutect2, varscan2
- RYR2 | c.14311G>A p.V4771I | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as rs794728804, CM024350, COSV63698747; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- ADGRL3 | c.3196T>C p.S1066P (on ENST00000506720 / NM_001322402.2; = p.S998P on NM_015236.6) | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV72231687; called by muse, mutect2, varscan2
- AL590132.1 | c.1355T>G p.L452R | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT tolerated, low confidence (0.08); catalogued as rs1346114013; called by muse, mutect2, varscan2
- ANK2 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV52145522; called by muse, mutect2, varscan2
- ARID1B | c.5771G>A p.W1924* | Nonsense Mutation (SNP) | VAF 56/410 reads (14%) | catalogued as rs1554237685; called by muse, mutect2, varscan2
- BRSK1 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1430498950, COSV58664665; called by muse, mutect2
- C8orf48 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 42/270 reads (16%) | catalogued as rs766448217; called by muse, mutect2, varscan2
- CCDC141 | c.3611A>T p.E1204V | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV55384719; called by muse, mutect2, varscan2
- CCPG1 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.296); catalogued as rs971801485; called by muse, mutect2, varscan2
- CDH18 | c.1799G>A p.C600Y | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780722499; called by muse, varscan2
- CDH20 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs759283649; called by muse, mutect2
- CHRM2 | c.958T>A p.S320T | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.828); catalogued as COSV57775026; called by muse, mutect2
- COL7A1 | c.7029A>C p.E2343D | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV60404503; called by mutect2, varscan2
- DAB1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 52/313 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs756329038, COSV100139913; called by muse, varscan2
- DLC1 | c.3783A>T p.K1261N (on ENST00000276297 / NM_001348081.2; = p.K824N on NM_006094.5) | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV52330348; called by muse, mutect2
- DPYSL3 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 60/327 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs372328515; called by muse, mutect2, varscan2
- EGFLAM | c.2489C>G p.T830R (on ENST00000354891 / NM_001205301.2; = p.A822G on NM_152403.4) | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV59314388; called by muse, mutect2, varscan2
- EHMT1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 68/385 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs777746839, COSV66044947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC8 | c.1058A>T p.Y353F (on ENST00000265038; = p.Y334F on NM_000082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV54019160; called by muse, mutect2, varscan2
- FLG2 | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 51/392 reads (13%) | catalogued as rs1200201140, COSV66167165; called by muse, mutect2, varscan2
- GAB2 | c.466C>T p.R156C (on ENST00000361507 / NM_080491.3; = p.R118C on NM_012296.3) | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs115330137, COSV60865934; called by muse, mutect2, varscan2
- HMX2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV60593225; called by muse, mutect2
- HSPA4L | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs779352330; called by muse, mutect2, varscan2
- IRX6 | c.1241A>G p.K414R | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51859779, COSV99306692; called by muse, mutect2, varscan2
- KCNV1 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 38/496 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52085692; called by muse, mutect2
- LHX3 | c.313C>T p.R105C (on ENST00000371748 / NM_178138.6; = p.R110C on NM_014564.5) | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1311780754, COSV65581190; called by muse, mutect2, varscan2
- LHX6 | c.1021G>A p.V341I (on ENST00000373755 / NM_001242334.2; = p.V370I on NM_014368.5) | Missense Mutation (SNP) | VAF 49/339 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as rs771003127, COSV104415142; called by muse, mutect2, varscan2
- MAGEC1 | c.2137A>G p.S713G | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs368437701; called by muse, mutect2
- MRC2 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1446902653; called by muse, mutect2, varscan2
- MTUS2 | c.2192A>C p.K731T | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV70918043, COSV70919467, COSV70920728; called by muse, mutect2, varscan2
- MYO1F | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.657); catalogued as rs996910823, COSV57795952; called by muse, mutect2
- NOS2 | c.1002C>T p.P334= | Splice Region (SNP) | VAF 22/197 reads (11%) | catalogued as COSV100569890; called by muse, mutect2, varscan2
- NUP133 | c.2884C>T p.R962C | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); catalogued as rs564675579, COSV54573201, COSV99772796; called by muse, mutect2, varscan2
- OR10A5 | c.781T>G p.F261V | Missense Mutation (SNP) | VAF 50/295 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV55055216; called by muse, mutect2, varscan2
- OR10T2 | c.55T>C p.S19P | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147666373, COSV57780708; called by muse, mutect2, varscan2
- OR11H2 | c.592A>G p.R198G (on ENST00000556246; = p.R209G on NM_001197287.1) | Missense Mutation (SNP) | VAF 32/1061 reads (3%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs754527180; called by muse, mutect2
- OR14K1 | c.494A>C p.N165T | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV51722034, COSV51722298; called by muse, varscan2
- OR4A16 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs1246240444, COSV59041776; called by muse, mutect2, varscan2
- OR51A4 | c.608T>C p.F203S | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV66749255; called by mutect2, varscan2
- OR9A2 | c.91T>G p.F31V | Missense Mutation (SNP) | VAF 63/381 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV63306646; called by muse, mutect2, varscan2
- PCDHB16 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 88/535 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs374286802; called by muse, mutect2, varscan2
- PDE3A | c.1813A>C p.S605R | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs759431662; called by muse, mutect2, varscan2
- PFKL | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1274426190; called by muse, mutect2, varscan2
- PPFIA4 | c.1819C>T p.R607C (on ENST00000447715; = p.R608C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs747344170, COSV55318855; called by muse, mutect2, varscan2
- PSMD1 | c.94A>C p.N32H | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs1559215446; called by muse, mutect2, varscan2
- RLIM | c.236A>C p.N79T | Missense Mutation (SNP) | VAF 49/336 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60329100; called by muse, mutect2, varscan2
- RYR3 | c.10328C>T p.P3443L (on ENST00000389232; = p.P3444L on NM_001036.6) | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.605); catalogued as rs777460190, COSV66789619, COSV66799846; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs201101225; called by muse, mutect2, varscan2
- SLAMF8 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 35/420 reads (8%) | catalogued as rs763656998; called by muse, mutect2
- SLC6A2 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54913557; called by muse, mutect2, varscan2
- SMG8 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs765179613, COSV56283532; called by muse, mutect2, varscan2
- SMOC1 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs751662427, COSV62759995; called by muse, mutect2, varscan2
- TRAPPC11 | c.632A>C p.K211T | Missense Mutation (SNP) | VAF 20/207 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs750025110; called by muse, mutect2
- TTN | c.85640C>T p.T28547I (on ENST00000591111; = p.T21123I on NM_003319.4) | Missense Mutation (SNP) | VAF 50/300 reads (17%) | PolyPhen benign (0.007); catalogued as rs1456715081, COSV60039201; called by muse, mutect2, varscan2
- TTN | c.75523G>A p.V25175I (on ENST00000591111; = p.V17751I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/346 reads (4%) | PolyPhen benign (0); catalogued as rs774092000; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.51611C>T p.T17204M (on ENST00000591111; = p.T9780M on NM_003319.4) | Missense Mutation (SNP) | VAF 53/390 reads (14%) | PolyPhen possibly damaging (0.584); catalogued as rs371571153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67139593; called by muse, mutect2, varscan2
- URI1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as COSV56350878; called by muse, mutect2
- VCAN | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147551428; called by muse, mutect2, varscan2
- ZFP82 | c.1489C>A p.L497M | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as rs765045185; called by muse, mutect2
- ZNF536 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs866467288, COSV62820141; called by muse, mutect2, varscan2
- ZSCAN4 | c.1142C>A p.T381N | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV56595011; called by muse, mutect2
- ABCA12 | c.2272T>G p.L758V (on ENST00000272895 / NM_173076.3; = p.L440V on NM_015657.3) | Missense Mutation (SNP) | VAF 37/238 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA12 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, varscan2
- ANKRD30B | c.1220C>G p.T407R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ANO2 | c.2538C>G p.H846Q (on ENST00000356134 / NM_001278597.3; = p.H850Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- APOB | c.6795A>C p.K2265N | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.715); called by muse, mutect2
- ASMT | c.684A>C p.E228D (on ENST00000381229; = p.E256D on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATAD2B | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ATP11C | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP5PB | c.264A>T p.L88F | Missense Mutation (SNP) | VAF 10/311 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2
- C10orf71 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 57/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C15orf39 | c.2690T>G p.L897R | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8orf48 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 48/340 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CACNB4 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CD1B | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 58/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1D | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 18/358 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); called by muse, mutect2
- CFAP47 | c.3591G>T p.K1197N | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.112); called by muse, mutect2
- CHD6 | c.3152G>A p.R1051K | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- COL6A5 | c.5482C>A p.Q1828K (on ENST00000312481; = p.Q1824K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPNE8 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 53/366 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CYP11B1 | c.1312T>G p.F438V | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DDX28 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- DHX37 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 43/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH9 | c.4434A>C p.Q1478H | Missense Mutation (SNP) | VAF 60/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH9 | c.8739A>C p.E2913D | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.209); called by muse, mutect2
- DNER | c.849T>G p.G283= | Splice Region (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- DPYS | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DRP2 | c.2420A>G p.K807R | Missense Mutation (SNP) | VAF 60/411 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1979T>C p.L660P (on ENST00000361735 / NM_015935.5; = p.L574P on NM_014955.3) | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- ELAVL2 | c.602A>C p.K201T | Missense Mutation (SNP) | VAF 47/359 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- EML5 | c.1057A>G p.S353G | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM184A | c.925T>G p.L309V | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- FOXP3 | c.776A>T p.H259L | Missense Mutation (SNP) | VAF 65/377 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSCB | c.1427T>G p.L476R | Missense Mutation (SNP) | VAF 45/288 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- FUT7 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2
- GFRA3 | c.149A>C p.K50T | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.583); called by muse, mutect2
- GLRA4 | c.968C>G p.A323G | Missense Mutation (SNP) | VAF 70/449 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- GLUD2 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 45/411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- IFT74 | c.1458T>A p.D486E | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- IGKV1D-43 | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 33/329 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- IL10RA | c.425A>T p.K142M | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1261C>A p.Q421K | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT tolerated, low confidence (0.93); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- IRX1 | c.288T>G p.Y96* | Nonsense Mutation (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
- KERA | c.491A>G p.N164S | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KLHDC1 | c.459_463del p.C153* | Frame Shift Del (DEL) | VAF 37/274 reads (14%) | called by mutect2, pindel, varscan2
- LAMA1 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 19/315 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LCORL | c.5345C>G p.S1782C | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC4C | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LTF | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- MAGEL2 | c.1699C>A p.P567T | Missense Mutation (SNP) | VAF 88/496 reads (18%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2, varscan2
- MAGI2 | c.3737C>T p.A1246V | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2
- MED17 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- METAP2 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MKRN3 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 59/374 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MKS1 | c.1153G>A p.D385N | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MOB4 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MYH11 | c.3835A>C p.N1279H | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- NELL2 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- NHS | c.4450C>T p.R1484* | Nonsense Mutation (SNP) | VAF 22/428 reads (5%) | called by muse, mutect2
- NKAIN2 | c.119A>C p.N40T | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NPAT | c.492T>G p.I164M | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2
- NRG3 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NXPE2 | c.64T>G p.L22V | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2
- OR2L3 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 59/345 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- OR3A3 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR51M1 | c.437T>C p.V146A | Missense Mutation (SNP) | VAF 51/398 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDH15 | c.5123A>C p.K1708T (on ENST00000644397 / NM_001354429.2; = p.K1650T on NM_001142771.2) | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- PCDHA7 | c.1187A>G p.K396R | Missense Mutation (SNP) | VAF 54/299 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- PEG3 | c.82A>T p.T28S | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEX1 | c.3724A>G p.R1242G | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- PIK3C3 | c.2437T>A p.S813T | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- PLEKHH3 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PNPLA2 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.012); called by muse, mutect2
- POLI | c.1244T>G p.L415R | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POMGNT1 | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 46/314 reads (15%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF17 | c.580A>C p.S194R | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PRRC2C | c.4307C>T p.P1436L (on ENST00000367742; = p.P1434L on NM_015172.4) | Missense Mutation (SNP) | VAF 48/295 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RCAN2 | c.146A>T p.K49M | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RIC8B | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RIPPLY1 | c.352T>G p.L118V | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF19A | c.37A>G p.N13D | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- RYR3 | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1G | c.799T>C p.C267R | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGCZ | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- SHH | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 75/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC13A5 | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.809); called by muse, mutect2
- SLC5A5 | c.82A>C p.T28P | Missense Mutation (SNP) | VAF 61/403 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- SLCO1B1 | c.1876T>G p.L626V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SLCO1C1 | c.1569T>A p.C523* | Nonsense Mutation (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- SNX14 | c.1214_1215del p.S405Nfs*2 (on ENST00000314673 / NM_001350535.1; = p.S361Nfs*2 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/134 reads (10%) | called by mutect2, varscan2
- STYX | c.243-1G>C p.X81_splice | Splice Site (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- TBL2 | c.427C>G p.R143G | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TENM3 | c.6182T>G p.V2061G | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TFAM | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TG | c.3659A>C p.N1220T | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TLN2 | c.7053A>T p.K2351N | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM132C | c.880A>C p.I294L | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TP53BP1 | c.5585+1G>A p.X1862_splice | Splice Site (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- TSEN2 | c.1381G>T p.D461Y | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- TTN | c.42658A>C p.S14220R (on ENST00000591111; = p.S6796R on NM_003319.4) | Missense Mutation (SNP) | VAF 31/213 reads (15%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.37832G>C p.C12611S (on ENST00000591111; = p.C5187S on NM_003319.4) | Missense Mutation (SNP) | VAF 40/400 reads (10%) | PolyPhen possibly damaging (0.503); called by muse, mutect2
- USH2A | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP9X | c.4025G>A p.R1342K | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UTP3 | c.1125A>C p.K375N | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- VCAN | c.2997A>C p.E999D | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- WDR49 | c.959T>G p.L320R (on ENST00000308378 / NM_001366158.1; = p.L661R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/537 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- XKR3 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 39/293 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF257 | c.1286A>C p.K429T | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ZNF677 | c.128A>C p.N43T | Missense Mutation (SNP) | VAF 42/387 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZNF679 | c.211A>C p.N71H | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF81 | c.1217A>C p.K406T | Missense Mutation (SNP) | VAF 62/410 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ABCC9 | c.2277T>G p.P759= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as COSV53983950, COSV53988521; called by muse, mutect2, varscan2
- ADCY8 | c.1752T>G p.T584= | Silent (SNP) | VAF 54/457 reads (12%) | catalogued as COSV53899574, COSV53915819; called by muse, mutect2, varscan2
- ADRA1B | c.1128C>A p.R376= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs1561612939, COSV100140557; called by muse, mutect2
- ANKRD52 | c.804G>A p.P268= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as rs183357245, COSV57285557; called by muse, varscan2
- ANKS1B | c.2943T>G p.T981= | Silent (SNP) | VAF 54/293 reads (18%) | catalogued as COSV100227353; called by muse, mutect2, varscan2
- ARHGEF6 | c.802T>C p.L268= | Silent (SNP) | VAF 23/221 reads (10%) | called by muse, mutect2, varscan2
- ATRX | c.6811A>C p.R2271= | Silent (SNP) | VAF 49/365 reads (13%) | catalogued as CM057844, COSV64876526; called by muse, mutect2, varscan2
- BRSK1 | c.2067C>T p.S689= | Silent (SNP) | VAF 45/247 reads (18%) | catalogued as rs768244070, COSV58668837; called by muse, mutect2, varscan2
- C8orf58 | c.696G>A p.P232= | Silent (SNP) | VAF 46/369 reads (12%) | catalogued as rs371627153; called by muse, mutect2, varscan2
- CCL7 | c.159G>A p.R53= | Silent (SNP) | VAF 49/341 reads (14%) | catalogued as COSV52336680; called by muse, mutect2, varscan2
- CDHR1 | c.2505C>T p.P835= | Silent (SNP) | VAF 76/420 reads (18%) | called by muse, mutect2, varscan2
- CHRNA1 | c.891T>G p.S297= (on ENST00000261007 / NM_001039523.3; = p.S272= on NM_000079.4) | Silent (SNP) | VAF 34/290 reads (12%) | called by muse, varscan2
- DCDC1 | c.2397A>G p.T799= | Silent (SNP) | VAF 24/259 reads (9%) | catalogued as rs764410332; called by muse, mutect2
- EPB41L3 | c.3183A>G p.K1061= | Silent (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- ESR1 | c.1083G>A p.A361= | Silent (SNP) | VAF 39/246 reads (16%) | catalogued as rs534325705; called by muse, mutect2, varscan2
- EYS | c.8055A>C p.G2685= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- GALNT14 | c.870T>G p.A290= | Silent (SNP) | VAF 12/345 reads (3%) | called by muse, mutect2
- GDF6 | c.78T>A p.A26= | Silent (SNP) | VAF 42/340 reads (12%) | called by muse, mutect2, varscan2
- GPR155 | c.663T>C p.F221= | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- GREM2 | c.186C>T p.V62= | Silent (SNP) | VAF 55/416 reads (13%) | called by muse, mutect2, varscan2
- HSD11B2 | c.585C>T p.G195= | Silent (SNP) | VAF 94/414 reads (23%) | catalogued as rs542287681, COSV52096883; called by muse, mutect2, varscan2
- ICAM5 | c.1032C>T p.C344= | Silent (SNP) | VAF 67/395 reads (17%) | catalogued as rs761291282; called by muse, mutect2, varscan2
- IGKV6D-41 | c.87T>C p.A29= | Silent (SNP) | VAF 41/195 reads (21%) | catalogued as rs762913029; called by muse, mutect2, varscan2
- IL4I1 | c.1098G>A p.E366= | Silent (SNP) | VAF 17/388 reads (4%) | catalogued as rs1234641884; called by muse, mutect2
- KCNK13 | c.318C>T p.T106= | Silent (SNP) | VAF 23/222 reads (10%) | catalogued as COSV56412374; called by muse, mutect2, varscan2
- KCNQ3 | c.2472G>A p.S824= | Silent (SNP) | VAF 56/484 reads (12%) | catalogued as rs774287489, COSV66473419, COSV66484458; called by muse, mutect2, varscan2
- KCNT1 | c.2076G>A p.A692= (on ENST00000488444; = p.A711= on NM_020822.3) | Silent (SNP) | VAF 66/417 reads (16%) | catalogued as rs755266973; ClinVar: likely benign; called by muse, mutect2, varscan2
- LPA | c.3024G>A p.R1008= | Silent (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- NLGN4X | c.264T>C p.F88= | Silent (SNP) | VAF 54/417 reads (13%) | called by muse, mutect2, varscan2
- OTOP1 | c.948C>T p.V316= | Silent (SNP) | VAF 48/368 reads (13%) | called by muse, mutect2, varscan2
- RFX8 | c.414C>T p.D138= (on ENST00000646446; = p.D67= on NM_001145664.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 51/320 reads (16%) | catalogued as rs369894843, COSV100959204; called by muse, varscan2
- ROCK2 | c.312T>G p.G104= | Silent (SNP) | VAF 11/227 reads (5%) | catalogued as rs889033651; called by muse, mutect2
- SCEL | c.234G>A p.E78= | Silent (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- SCRN1 | c.1056G>A p.E352= | Silent (SNP) | VAF 31/294 reads (11%) | called by muse, mutect2, varscan2
- SFRP2 | c.243G>A p.P81= | Silent (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- SLCO3A1 | c.318G>A p.P106= | Silent (SNP) | VAF 62/412 reads (15%) | catalogued as rs1450833342, COSV59225607; called by muse, mutect2, varscan2
- SLITRK2 | c.2478G>A p.P826= | Silent (SNP) | VAF 63/418 reads (15%) | catalogued as rs151106789, COSV59425515; called by muse, mutect2, varscan2
- SPOCD1 | c.1614T>C p.P538= | Silent (SNP) | VAF 43/208 reads (21%) | called by muse, mutect2, varscan2
- STAC | c.63C>T p.G21= | Silent (SNP) | VAF 63/347 reads (18%) | called by muse, mutect2, varscan2
- TCF21 | c.411C>T p.N137= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs755012233, COSV52818420; called by muse, mutect2
- TCF4 | c.114T>C p.T38= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as COSV61893895; called by muse, mutect2, varscan2
- TPSD1 | c.234C>T p.T78= | Silent (SNP) | VAF 116/461 reads (25%) | catalogued as rs202070225; called by muse, mutect2, varscan2
- TRHDE | c.2385G>T p.P795= | Silent (SNP) | VAF 33/220 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.35770A>C p.R11924= (on ENST00000591111; = p.R4500= on NM_003319.4) | Silent (SNP) | VAF 10/248 reads (4%) | called by muse, mutect2
- VWDE | c.1059T>G p.S353= | Silent (SNP) | VAF 36/235 reads (15%) | called by muse, mutect2, varscan2
- WLS | c.1080A>G p.Q360= | Silent (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- ZC3H7A | c.1212C>T p.F404= | Silent (SNP) | VAF 12/288 reads (4%) | catalogued as COSV63270869; called by muse, mutect2
- ZNF71 | c.1320C>T p.C440= | Silent (SNP) | VAF 68/468 reads (15%) | catalogued as COSV60147580; called by muse, mutect2, varscan2
- AC016747.1 | n.463T>G | RNA (SNP) | VAF 75/301 reads (25%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822368 A>C | 5'Flank (SNP) | VAF 42/273 reads (15%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2350-2892A>C | Intron (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- FOSB | c.447+63T>C | Intron (SNP) | VAF 61/355 reads (17%) | called by muse, mutect2, varscan2
- L1CAM | c.-75C>T | 5'UTR (SNP) | VAF 48/291 reads (16%) | catalogued as rs782329646; called by muse, mutect2, varscan2
- MAF | c.*4245A>C | 3'UTR (SNP) | VAF 22/308 reads (7%) | catalogued as COSV100391602, COSV58155127; called by muse, mutect2
- NUDT18 | c.-30G>T | 5'UTR (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- RBM44 | c.-98-2863A>G | Intron (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- UNC13B | c.761+6476T>G | Intron (SNP) | VAF 39/252 reads (15%) | called by muse, mutect2, varscan2
